Surgical pathology report (de-identified scan), TCGA case TCGA-08-0360, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0360-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA-08-0360

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, right temporal lobe, biopsy: Glioblastoma multiforme; see comment.
- B. Brain, right temporal lobe, biopsy: Glioblastoma multiforme; see comment.

COMMENT: Sections show an infiltrating glioma composed of mitotically active, pleomorphic cells with hyperchromatic nuclei and coarse chromatin. Vascular proliferation is seen in part A, and palisading around areas of necrosis is found in part B. The findings are those of glioblastoma multiforme.

Intraoperative Diagnosis

FS1 (A) Brain, biopsy: Malignant glioma, favor glioblastoma multiforme. Tissue section and cytologic preparation. [REDACTED]

Gross Description

The specimen is received in two parts, each labeled with the patient's name and medical record number.

Part A is received fresh and is additionally labeled "#2 tumor frozen." It consists of a single fragment of glistening, gray-tan, soft tissue, measuring 1.0 x 0.4 x 0.3 cm. Approximately 30-40% of the tissue is slightly more yellow in color. A portion of this yellow tissue is submitted for cytologic prep, and approximately 30% of the remaining tissue is submitted for frozen section diagnosis as FS1, with the frozen section remnant submitted in cassette A1. The remaining unfrozen tissue is entirely submitted in cassette A2.

Part B, additionally labeled "tumor (permanent)," consists of two irregularly shaped fragments of tan-gray, soft tissue measuring 0.7 x 0.7 x 0.3 cm in aggregate. The specimen is entirely submitted in cassette B1.

Clinical History

The patient is a [REDACTED] with a right temporal ring-enhancing lesion. He undergoes biopsy.

[page 2 of 2]
Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file ea5643ac-274f-4527-87e4-976b36ebf28c (TCGA-08-0360.DA716F97-21F8-4F95-870E-D3CB17CA7585.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).